Somatic mutation profile of tumor specimen TCGA-13-0724-01A (aliquot TCGA-13-0724-01A-01W-0372-09) from TCGA case TCGA-13-0724, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.1 years (26,342 days).
Specimen TCGA-13-0724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07042e85-b5b8-43dc-b985-4fd2f8663d8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0724-10B (Blood Derived Normal), aliquot TCGA-13-0724-10B-01W-0372-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58f01895-1738-4ca4-98d1-a6f9d370b803

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 60/77 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP1M2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs376655050, COSV51568967; called by muse, mutect2, varscan2
- BCL9 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 71/459 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as COSV52348685; called by muse, mutect2, varscan2
- CREBBP | c.2509_2515del p.G837Rfs*10 | Frame Shift Del (DEL) | VAF 41/47 reads (87%) | catalogued as COSV52135800; called by mutect2, pindel, varscan2
- DPYD | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64609955; called by muse, mutect2, varscan2
- ELOA2 | c.1622C>A p.P541Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV55294759, COSV55305410; called by muse, mutect2, varscan2
- FAM160B1 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 7/162 reads (4%) | catalogued as rs1216773850; called by muse, mutect2
- FGF5 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV56889985, COSV56891429; called by muse, mutect2, varscan2
- FMO5 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 196/314 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs781855435, COSV54206201, COSV54209612; called by muse, mutect2, varscan2
- GABRQ | c.1466A>G p.H489R | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64783525; called by muse, mutect2, varscan2
- GMCL1 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57002986; called by muse, mutect2, varscan2
- GRB14 | c.1047T>A p.N349K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1229161916, COSV55741738; called by muse, mutect2, varscan2
- KRCC1 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1370244999, COSV61252047; called by muse, mutect2, varscan2
- KRR1 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 219/672 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs368830982; called by muse, mutect2, varscan2
- LUZP4 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64219540; called by muse, mutect2, varscan2
- MMRN1 | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV53341266; called by muse, mutect2, varscan2
- MTHFD1L | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV66226847; called by muse, mutect2, varscan2
- NAA20 | c.267del p.A90Lfs*7 | Frame Shift Del (DEL) | VAF 54/328 reads (16%) | catalogued as COSV58548088; called by mutect2, pindel, varscan2
- NCOA6 | c.4045T>G p.S1349A | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV62866698; called by muse, mutect2, varscan2
- NOTCH3 | c.5280C>G p.I1760M | Missense Mutation (SNP) | VAF 147/298 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54644459; called by muse, mutect2, varscan2
- NT5C1B | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs199544140, COSV58398139; called by muse, mutect2, varscan2
- OR8J1 | c.287A>C p.E96A | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV57319586; called by muse, mutect2
- OR8U1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100163984, COSV56418132; called by muse, mutect2, varscan2
- PHTF1 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63368583; called by muse, mutect2, varscan2
- PSG1 | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 136/358 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); catalogued as rs781260860, COSV54944520; called by muse, mutect2, varscan2
- RIOX2 | c.1022C>G p.P341R (on ENST00000333396 / NM_001042533.2; = p.P340R on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753392377, COSV51714857; called by mutect2, varscan2
- SLITRK3 | c.2228T>A p.I743N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV53852053; called by muse, mutect2, varscan2
- SPATA31A3 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 217/236 reads (92%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1178213611; called by muse, mutect2, varscan2
- TBC1D8B | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV52182206; called by muse, mutect2, varscan2
- TRAPPC13 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51559750; called by muse, mutect2, varscan2
- KIF1B | c.2449G>A p.D817N (on ENST00000377086 / NM_001365952.1; = p.D771N on NM_015074.3) | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- MMP19 | c.1263_1265del p.L421del | In Frame Del (DEL) | VAF 57/237 reads (24%) | called by mutect2, pindel, varscan2
- ABCC5 | c.4221G>A p.E1407= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV55594673; called by muse, mutect2, varscan2
- CARD14 | c.2319C>T p.I773= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs747692472, COSV60125861; called by muse, mutect2, varscan2
- DPP3 | c.2037T>G p.L679= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV64757658; called by muse, mutect2, varscan2
- FBN3 | c.6039G>C p.R2013= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV54469008, COSV99560178; called by muse, mutect2, varscan2
- NOTCH3 | c.5028C>T p.F1676= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV54644478; called by muse, mutect2, varscan2
- NOTCH3 | c.4960C>T p.L1654= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV54644504; called by muse, mutect2, varscan2
- SDC3 | c.453G>A p.E151= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV59580231; called by muse, mutect2, varscan2
- SEMA3C | c.819G>C p.L273= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV54853318; called by muse, mutect2, varscan2
- SLX4 | c.1242C>T p.D414= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs773150424, COSV53567211; called by muse, mutect2, varscan2
- ZNF557 | c.1131C>T p.S377= (on ENST00000414706 / NM_001044388.2; = p.S384= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs1230624919, COSV53274973; called by muse, mutect2, varscan2
- SON | c.6657+162T>A | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51667226; called by muse, mutect2, varscan2
